Gene-level copy-number profile of tumor specimen TCGA-AO-A03P-01A from TCGA case TCGA-AO-A03P, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 54.0 years (19,724 days).
Specimen TCGA-AO-A03P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.1ec0101f-dc3b-4d2e-b182-b70350f92562.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A03P-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 826 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9fabee8f-fe3c-4bdd-ba68-6ad50c795870

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 666; copy number 2: 4,345; copy number 3: 13,479; copy number 4: 26,010; copy number 5: 5,221; copy number 6: 5,856; copy number 7: 924; copy number 8: 626; copy number 9: 961; copy number 10: 131; copy number 11: 416; copy number 12: 43; copy number 13: 96; copy number 14: 106; copy number 15: 161; copy number 17: 26; copy number 18: 86; copy number 19: 63; copy number 20: 52; copy number 21: 50; copy number 22: 79; copy number 23: 121; copy number 24: 47; copy number 26: 32; copy number 27: 1; copy number 29: 42; copy number 30: 58; copy number 31: 15; copy number 33: 12; copy number 34: 4; copy number 36: 25; copy number 38: 9; copy number 39: 23; copy number 48: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A03P-01A-11D-A011-01): tumor purity 0.78, ploidy 4.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,670 genes in 63 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:60,026,298–61,821,246, 16 genes, copy number 11 (within-gene range 4–11): ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625.
- chr10:63,465,229–65,141,185, 16 genes, copy number 19: JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1, RPL7AP50, AC012558.1, DBF4P1, RPL17P35, CYP2C61P, ANXA2P3, LINC02671, NEK4P3, AL513321.2.
- chr10:66,837,457–68,407,294, 27 genes, copy number 10–24: AL607023.1, LRRTM3, AL139240.1, RPL7AP51, MIR7151, AKR1B10P1, RPL21P92, DNAJC12, RNU6-1250P, RN7SL394P, DNAJC19P1, AL133551.1, RNU6-523P, RPL12P8, SIRT1, HERC4, RPS3AP38, RN7SL220P, POU5F1P5, MYPN, RN7SKP202, ATOH7, LINC02640, KRT19P4, PBLD, HNRNPH3, RUFY2.
- chr10:69,123,512–72,054,037, 63 genes, copy number 18–39 (broad region; genes not listed).
- chr10:72,501,746–76,836,861, 122 genes, copy number 10–23 (broad region; genes not listed).
- chr10:78,176,928–78,675,109, 7 genes, copy number 18 (within-gene range 7–18): AL731555.1, AC012560.1, LINC00595, AC010163.3, AC010163.1, AC010163.2, SNORA71.
- chr10:78,696,062–79,445,624, 7 genes, copy number 18 (within-gene range 7–18): AC016820.1, ZMIZ1-AS1, AL356753.1, ZMIZ1, PPIF, ZCCHC24, AL133481.1.
- chr10:80,046,860–81,137,335, 27 genes, copy number 9 (within-gene range 7–9): TMEM254-AS1, AL356095.3, TMEM254, AL356095.2, RPL22P18, PLAC9, ANXA11, LINC00857, RPS12P2, AL513174.1, EIF5AP4, AL359195.2, MAT1A, ZNF519P1, AL359195.1, DYDC1, DYDC2, PRXL2A, TSPAN14, AC021028.1, SH2D4B, LINC02655, RPS7P9, AC027673.1, FARSBP1, WARS2P1, RPA2P2.
- chr10:83,067,962–85,432,775, 27 genes, copy number 13 (within-gene range 4–13): RNU6-478P, MARK2P15, LINC02650, AC069540.2, AC069540.1, RNU6-129P, AL390786.1, RNU1-65P, HMGN2P8, AL603756.1, GHITM, CERNA2, C10orf99, CDHR1, LRIT2, RGR, LRIT1, LINC00858, CCSER2, RPL12P29, TNPO1P1, CACYBPP1, RPS3AP5, AL358787.2, LINC01519, AL358787.1, LINC02647.
- chr10:94,865,852–96,359,365, 35 genes, copy number 24: CYP2C58P, RPL7AP52, CYP2C9, MTND4P20, CYP2C59P, CYP2C60P, AL359672.1, CYP2C8, AL157834.1, AL157834.4, AL157834.3, PAWRP1, ACSM6, AL157834.2, PDLIM1, SORBS1, RPS3AP36, ALDH18A1, TCTN3, ENTPD1, ENTPD1-AS1, AL365273.1, AL365273.2, CC2D2B, RPL21P90, CCNJ, MIR3157, RNU6-271P, AC021037.1, ZNF518A, BLNK, NPM1P25, AL136181.1, DNTT, OPALIN.
- chr10:129,278,251–131,311,721, 24 genes, copy number 20: AL391869.1, AL359508.1, MGMT, AL355531.1, AL157832.2, AL157832.1, LINC02666, EBF3, AL354950.2, MIR4297, AL354950.1, AL354950.3, C10orf143, AL139123.1, CTAGE7P, PPIAP32, GLRX3, LINC02646, AL157712.1, Y_RNA, AC016816.1, MIR378C, TCERG1L, TCERG1L-AS1.
- chr10:132,332,154–133,358,025, 32 genes, copy number 21: LRRC27, PWWP2B, AL451069.2, AL451069.3, LINC02870, AL451069.1, LINC01165, INPP5A, NKX6-2, CFAP46, LINC01166, LINC01167, LINC01168, ADGRA1, ADGRA1-AS1, RPL5P28, KNDC1, UTF1, VENTX, MIR202HG, MIR202, AL592071.1, ADAM8, TUBGCP2, AL360181.2, ZNF511, ZNF511-PRAP1, CALY, BANF1P2, AL360181.1, PRAP1, FUOM.
- chr15:42,537,820–43,604,901, 38 genes, copy number 11–22 (within-gene range 5–22): LRRC57, HAUS2, AC018362.2, MYL12BP1, STARD9, EIF4EBP2P2, CDAN1, AC090510.3, AC090510.2, TTBK2, AC090510.1, AC090510.4, KRT8P50, FDPSP4, UBR1, AC068724.3, AC068724.2, RPS3AP47, TMEM62, SPCS2P1, AC068724.4, AC068724.1, CCNDBP1, EPB42, TGM5, Y_RNA, ATP5PDP1, TGM7, AC009852.1, LCMT2, ADAL, ZSCAN29, TUBGCP4, RN7SL487P, TP53BP1, MAP1A, PPIP5K1, CKMT1B.
- chr15:45,167,214–47,134,122, 43 genes, copy number 9–29 (within-gene range 5–29): SHF, AC051619.3, AC051619.6, AC051619.7, AC051619.9, AC051619.8, H3P39, AC051619.4, SLC28A2, AC051619.10, AC051619.1, AC051619.2, RNU6-953P, GATM, AC025580.3, SPATA5L1, C15orf48, AC025580.1, MIR147B, AC025580.2, SLC30A4, HMGN2P46, SNORA41B, AC090527.1, DPPA5P2, AC090527.3, BLOC1S6, AC090527.2, Y_RNA, SQOR, AC068722.2, AC068722.1, AC068714.1, AC091074.3, MTND5P40, AC091074.1, AC091074.2, AC012405.1, RNU6-1014P, AC073941.1, RN7SKP101, AC073941.2, AC066615.1.
- chr15:47,944,044–55,993,746, 161 genes, copy number 22–30 (within-gene range 7–30) (broad region; genes not listed).
- chr15:60,419,609–61,229,302, 14 genes, copy number 24–38 (within-gene range 3–38): ICE2, RORA-AS1, RORA, AC107241.1, CYCSP38, AC009560.1, AC009560.3, AC009560.4, AC009560.2, RORA-AS2, RNA5SP397, AC022898.1, AC022898.2, AC012404.1.
- chr15:70,047,790–71,783,383, 30 genes, copy number 9 (within-gene range 4–9): TLE3, MIR629, RNU6-745P, AC026583.1, AC048383.1, LINC02205, AC009434.1, LINC02204, AC087699.1, SALRNA3, SALRNA2, UACA, AC009269.2, AC009269.5, AC009269.3, AC009269.1, RPL29P30, LARP6, AC009269.4, LRRC49, KRT8P9, THAP10, RPL5P3, THSD4, CT62, THSD4-AS1, HMGB1P6, AC064799.2, AC064799.1, AC108861.1.
- chr15:73,560,014–74,336,472, 27 genes, copy number 9 (within-gene range 8–9): NPTN, NPTN-IT1, CD276, AC022188.1, INSYN1, INSYN1-AS1, AC018943.1, TBC1D21, LOXL1-AS1, LOXL1, STOML1, PML, AC013486.1, DNM1P33, GOLGA6A, RN7SL429P, COMMD4P2, ISLR2, AC010931.1, AC010931.2, Metazoa_SRP, ISLR, STRA6, CCDC33, AC023300.3, AC023300.1, AC023300.2.
- chr15:76,336,773–77,083,984, 15 genes, copy number 14: ISL2, AC027243.1, AC027243.2, SCAPER, AC090751.1, MIR3713, RN7SKP217, RCN2, RN7SL278P, KRT8P23, PSTPIP1, TSPAN3, AC090181.1, AC090181.3, AC090181.2.
- chr15:80,263,068–82,739,122, 68 genes, copy number 11–26 (within-gene range 5–26) (broad region; genes not listed).
- chr15:84,817,356–85,330,334, 16 genes, copy number 13–34: ALPK3, AC012291.1, SLC28A1, AC087468.2, RNU6-339P, RNU6-796P, AC087468.1, PDE8A, AC044860.2, AC044860.1, NIFKP8, CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3.
- chr15:87,859,751–88,875,353, 17 genes, copy number 14 (within-gene range 6–14): NTRK3, MED28P6, NTRK3-AS1, MRPL46, AC013489.1, MRPS11, AC013489.3, DET1, AC013489.2, LINC01586, MIR1179, MIR7-2, MIR3529, AEN, ISG20, AC103982.1, ACAN.
- chr15:89,748,661–90,234,047, 25 genes, copy number 36 (within-gene range 4–36): MESP1, MRPL15P1, MESP2, ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1.
- chr15:97,540,597–99,251,223, 34 genes, copy number 21–48: AC026523.1, AC026523.3, AC026523.4, LINC00923, AC024651.2, AC024651.3, ARRDC4, AC024651.1, LINC02251, U6, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2, AC015722.1, AC015722.2, LINC02351, FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1.
- chr15:100,919,327–101,614,531, 19 genes, copy number 19 (within-gene range 4–19): LRRK1, AC090907.1, AC090907.2, AC090907.3, AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348.
- chr18:24,534,551–25,056,760, 7 genes, copy number 10–19 (within-gene range 10–21): LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1.
- chr18:26,098,839–80,247,514, 762 genes, copy number 9–26 (broad region; genes not listed).
- chr19:36,850,361–37,403,846, 22 genes, copy number 9: ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535, AC016590.4, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1.
- chr19:48,296,457–51,035,230, 209 genes, copy number 9 (broad region; genes not listed).
- chr19:51,888,025–55,988,629, 333 genes, copy number 11 (broad region; genes not listed).
- chr19:57,191,500–58,481,230, 110 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr20:34,928,432–35,147,336, 8 genes, copy number 15: GSS, MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P, EDEM2, AL135844.1.
- chr20:40,004,216–41,331,660, 17 genes, copy number 9: LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1.
- chr20:46,345,980–46,864,104, 16 genes, copy number 13: SLC35C2, AL133227.1, ELMO2, ZNF663P, AL031686.1, MKRN7P, ZNF840P, ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1.
- chr20:47,160,838–47,493,085, 10 genes, copy number 15: AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P.
- chr20:48,007,875–49,046,168, 18 genes, copy number 17: AL139351.2, AL139351.3, AL139351.1, AL136102.1, AL121888.2, AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2, RNU7-144P, PREX1, AL035106.1, AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1.
- chr20:49,503,874–54,651,169, 94 genes, copy number 10–26 (within-gene range 2–26) (broad region; genes not listed).
- chr20:55,408,898–56,205,173, 7 genes, copy number 9–15: LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1, CBLN4, RNA5SP487.
- chr20:56,601,701–56,786,087, 7 genes, copy number 17: RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P.
- chr20:57,488,392–62,296,213, 90 genes, copy number 9–19 (within-gene range 6–19) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 666. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
